Somatic mutation profile of tumor specimen TCGA-B6-A0I6-01A (aliquot TCGA-B6-A0I6-01A-11W-A100-09) from TCGA case TCGA-B6-A0I6, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 49.3 years (18,014 days).
Specimen TCGA-B6-A0I6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b5ae874-714b-48ba-84b5-ac79f42f5d22.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0I6-10A (Blood Derived Normal), aliquot TCGA-B6-A0I6-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35476cb8-f74b-4a24-bb40-b1eb6da2293b

The open-access MAF lists 90 somatic variants for this specimen: 70 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 19, Nonsense Mutation 5, Frame Shift Del 2, Splice Region 1, Intron 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALMS1 | c.6816G>A p.M2272I | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765233946; ClinVar: uncertain significance; called by muse, mutect2
- ARID3B | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV60559168; called by muse, mutect2, varscan2
- ARID4B | c.893A>G p.E298G | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.714); catalogued as COSV51611354; called by muse, mutect2
- ATP10D | c.4115G>A p.G1372E | Missense Mutation (SNP) | VAF 71/217 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763021315, COSV56699512; called by muse, mutect2, varscan2
- BMP1 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as COSV60483946; called by muse, mutect2, varscan2
- C15orf39 | c.458G>T p.R153M | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); catalogued as COSV62298271; called by muse, mutect2
- CABIN1 | c.656G>A p.C219Y | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.358); catalogued as rs755174243, COSV54089323; called by muse, mutect2, varscan2
- CDK15 | c.1157A>T p.Y386F (on ENST00000652192 / NM_001366386.2; = p.Y335F on NM_139158.2) | Missense Mutation (SNP) | VAF 120/169 reads (71%) | SIFT tolerated (0.43); PolyPhen benign (0.104); catalogued as COSV53638657; called by muse, mutect2, varscan2
- COL22A1 | c.4486C>A p.Q1496K | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.93); PolyPhen benign (0.315); catalogued as COSV57348141, COSV57361247; called by muse, mutect2, varscan2
- CRAT | c.307C>T p.L103F | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.169); catalogued as COSV58879234; called by muse, mutect2, varscan2
- CSPG5 | c.418C>A p.P140T | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.341); catalogued as COSV53132182, COSV53133928; called by muse, mutect2, varscan2
- DCHS2 | n.4237T>A | Splice Region (SNP) | VAF 58/112 reads (52%) | catalogued as rs773058478, COSV61779830; called by muse, mutect2, varscan2
- DNAH6 | c.1921C>G p.P641A | Missense Mutation (SNP) | VAF 44/191 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV52858617, COSV52884109; called by muse, mutect2, varscan2
- DSE | c.1494G>T p.W498C | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59067482; called by muse, mutect2, varscan2
- FAT3 | c.8961G>T p.K2987N | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV53174951; called by muse, mutect2, varscan2
- FGL2 | c.1050C>A p.N350K | Missense Mutation (SNP) | VAF 74/198 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV50385907; called by muse, mutect2, varscan2
- GABRA3 | c.1007C>T p.T336M | Missense Mutation (SNP) | VAF 95/219 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64801472; called by muse, mutect2, varscan2
- GABRA4 | c.650A>C p.E217A | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51935347; called by muse, mutect2
- GLB1L | c.1790G>A p.G597E | Missense Mutation (SNP) | VAF 97/159 reads (61%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as rs773572669, COSV55478882; called by muse, mutect2, varscan2
- GPD1 | c.548C>T p.T183I | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1363038579, COSV56549188; called by muse, mutect2, varscan2
- H6PD | c.190G>T p.G64* | Nonsense Mutation (SNP) | VAF 24/65 reads (37%) | catalogued as COSV66232385; called by muse, mutect2, varscan2
- HMCN1 | c.9509C>T p.T3170I | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.403); catalogued as COSV54942336; called by muse, mutect2, varscan2
- HMGCS2 | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 138/404 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as rs939049952, COSV65569313; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HUWE1 | c.12240G>C p.L4080F | Missense Mutation (SNP) | VAF 78/306 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53364095; called by muse, mutect2, varscan2
- IL12RB1 | c.634C>T p.R212* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as rs772438756, CM136625, COSV59099458; called by mutect2, varscan2
- KIF21B | c.3193A>T p.T1065S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as COSV59766935; called by muse, mutect2, varscan2
- KLHL4 | c.1157C>A p.T386N | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64139118, COSV64148017; called by muse, mutect2, varscan2
- LAMA1 | c.4667G>C p.C1556S | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67544539; called by muse, mutect2, varscan2
- LEMD3 | c.26C>A p.P9H | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV57653961; called by muse, varscan2
- LRRC34 | c.1020C>G p.N340K (on ENST00000446859 / NM_001172779.2; = p.N308K on NM_153353.5) | Missense Mutation (SNP) | VAF 72/249 reads (29%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as COSV57187750, COSV57188010; called by muse, mutect2, varscan2
- LUZP2 | c.90G>T p.Q30H | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61219005; called by muse, mutect2, varscan2
- LYG2 | c.457A>T p.T153S | Missense Mutation (SNP) | VAF 101/364 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.197); catalogued as COSV60716671; called by muse, mutect2, varscan2
- MATN2 | c.156G>T p.E52D | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV54719538; called by muse, mutect2, varscan2
- MBTPS1 | c.2513G>A p.G838E | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.79); PolyPhen benign (0.012); catalogued as rs1475304119; called by muse, mutect2, varscan2
- MED12 | c.6490A>G p.N2164D | Missense Mutation (SNP) | VAF 77/281 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.074); catalogued as COSV61356086; called by muse, mutect2, varscan2
- NCOR1 | c.5521G>C p.E1841Q | Missense Mutation (SNP) | VAF 56/102 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.398); catalogued as COSV51990680; called by muse, mutect2, varscan2
- NOS1 | c.228C>A p.S76R | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.568); catalogued as COSV57617267; called by muse, mutect2
- NSD2 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56396653; called by muse, mutect2, varscan2
- NYNRIN | c.3331T>C p.Y1111H | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1025809274, COSV66845123; called by muse, mutect2, varscan2
- OSMR | c.604A>G p.S202G | Missense Mutation (SNP) | VAF 59/219 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV57092103; called by muse, mutect2, varscan2
- PC | c.619G>C p.V207L | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as COSV63082711; called by muse, mutect2, varscan2
- PDE3A | c.2123G>A p.G708D | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV62983071; called by muse, mutect2, varscan2
- PKHD1L1 | c.5009C>A p.S1670* | Nonsense Mutation (SNP) | VAF 9/172 reads (5%) | catalogued as COSV65736553; called by muse, mutect2
- PKHD1L1 | c.6668G>C p.G2223A | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65753470; called by muse, mutect2
- PRKDC | c.5228T>A p.M1743K | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV58064028; called by muse, mutect2, varscan2
- PTPRO | c.1810T>C p.Y604H | Missense Mutation (SNP) | VAF 37/258 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); catalogued as COSV55523176; called by muse, mutect2, varscan2
- PYGM | c.1904C>T p.P635L | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs368385152; called by muse, mutect2, varscan2
- RLF | c.2606A>G p.D869G | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV65653235; called by muse, mutect2, varscan2
- RNF213 | c.14951A>G p.D4984G | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as COSV60409179; called by muse, mutect2, varscan2
- RWDD3 | c.353C>G p.P118R | Missense Mutation (SNP) | VAF 9/165 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.28); catalogued as rs1472738415, COSV55721437; called by muse, mutect2
- SARS1 | c.530T>G p.V177G | Missense Mutation (SNP) | VAF 96/318 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV52323320; called by muse, mutect2, varscan2
- SLC7A14 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 67/149 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.196); catalogued as COSV51590293; called by muse, mutect2, varscan2
- TCTN2 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 91/136 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs769556542, COSV57635043; called by muse, mutect2, varscan2
- TEX15 | c.1632A>C p.R544S (on ENST00000256246; = p.R927S on NM_001350162.2) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.074); catalogued as COSV56353945; called by muse, mutect2, varscan2
- THADA | c.2213G>A p.S738N | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.058); catalogued as COSV57693450; called by muse, mutect2, varscan2
- TP53 | c.531_532del p.H178Pfs*2 | Frame Shift Del (DEL) | VAF 73/128 reads (57%) | catalogued as COSV52890853; called by mutect2, pindel, varscan2
- TTN | c.23247T>A p.D7749E (on ENST00000591111; = p.D6822E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/58 reads (66%) | PolyPhen benign (0.001); catalogued as COSV60354712; called by muse, mutect2, varscan2
- UCP2 | c.906C>A p.C302* | Nonsense Mutation (SNP) | VAF 43/177 reads (24%) | catalogued as COSV60105314; called by muse, mutect2, varscan2
- UPF1 | c.719C>G p.S240C | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV53201979; called by muse, mutect2
- VIT | c.517C>A p.P173T | Missense Mutation (SNP) | VAF 94/281 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV64899271; called by muse, mutect2, varscan2
- VPS13B | c.2468C>T p.S823F | Missense Mutation (SNP) | VAF 21/735 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as COSV62026093; called by muse, mutect2
- ZEB1 | c.2021C>A p.T674K | Missense Mutation (SNP) | VAF 49/230 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV58055090; called by muse, mutect2, varscan2
- ZNF335 | c.2174C>G p.S725C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV59820289; called by muse, mutect2, varscan2
- ZSWIM5 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 75/190 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.077); catalogued as rs374367203; called by muse, mutect2, varscan2
- DGKA | c.440_457del p.E147_D152del | In Frame Del (DEL) | VAF 32/199 reads (16%) | called by pindel, varscan2
- ITPRID1 | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 14/257 reads (5%) | called by muse, mutect2
- LILRB5 | c.1521C>A p.D507E (on ENST00000449561 / NM_001081442.3; = p.D506E on NM_006840.5) | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.221); called by muse, mutect2
- SUPT20H | c.1547G>C p.S516T (on ENST00000350612 / NM_001014286.3; = p.S517T on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/354 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.276); called by muse, mutect2
- ZNF808 | c.663_687del p.K221Nfs*18 | Frame Shift Del (DEL) | VAF 27/102 reads (26%) | called by mutect2, pindel, varscan2
- ZSCAN5B | c.740-28_744del p.X247_splice | Splice Site (DEL) | VAF 29/145 reads (20%) | called by mutect2, pindel, varscan2
- CCDC82 | c.600C>T p.I200= | Silent (SNP) | VAF 207/429 reads (48%) | catalogued as COSV53595509; called by muse, mutect2, varscan2
- CELF6 | c.1428T>C p.D476= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV54718961; called by muse, mutect2, varscan2
- CEMIP | c.1482G>T p.L494= | Silent (SNP) | VAF 34/1043 reads (3%) | called by muse, mutect2
- EFCAB12 | c.708G>A p.E236= | Silent (SNP) | VAF 113/301 reads (38%) | catalogued as COSV58178896; called by muse, mutect2, varscan2
- ITLN1 | c.417C>T p.Y139= | Silent (SNP) | VAF 31/204 reads (15%) | catalogued as rs1355520323, COSV58276888; called by muse, mutect2, varscan2
- KCNA6 | c.882C>T p.N294= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as COSV54978041; called by muse, mutect2, varscan2
- LCN8 | c.204C>G p.T68= (on ENST00000612714 / NM_001345934.1; = p.T45= on NM_178469.3) | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV60211354; called by muse, mutect2, varscan2
- LRRK1 | c.3444G>A p.L1148= | Silent (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- MAGEB3 | c.6T>C p.P2= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as COSV64397739; called by muse, mutect2, varscan2
- MYO18B | c.2949C>T p.T983= | Silent (SNP) | VAF 122/351 reads (35%) | catalogued as COSV59149017; called by muse, mutect2, varscan2
- OR1S1 | c.810C>T p.G270= | Silent (SNP) | VAF 42/131 reads (32%) | catalogued as rs769712075, COSV58708680; called by muse, mutect2, varscan2
- PDZRN3 | c.735C>A p.T245= | Silent (SNP) | VAF 42/67 reads (63%) | catalogued as COSV55215746; called by muse, mutect2, varscan2
- PKDREJ | c.5019A>C p.I1673= | Silent (SNP) | VAF 36/102 reads (35%) | catalogued as COSV53553283; called by muse, mutect2, varscan2
- RXRG | c.1326C>T p.L442= | Silent (SNP) | VAF 77/183 reads (42%) | catalogued as COSV63233135; called by muse, mutect2, varscan2
- SEPTIN5 | c.321G>C p.V107= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV63531026; called by muse, mutect2, varscan2
- SLC12A9 | c.915C>T p.A305= | Silent (SNP) | VAF 72/330 reads (22%) | catalogued as rs767360616, COSV51937151; called by muse, mutect2, varscan2
- SLC22A2 | c.312G>C p.V104= | Silent (SNP) | VAF 5/75 reads (7%) | called by muse, mutect2
- TARS2 | c.1518C>T p.C506= | Silent (SNP) | VAF 43/152 reads (28%) | catalogued as rs1163661043, COSV64696927; called by muse, mutect2, varscan2
- VMP1 | c.1035A>G p.Q345= | Silent (SNP) | VAF 110/151 reads (73%) | catalogued as COSV51872559; called by muse, mutect2, varscan2
- DST | c.4297-4750A>T | Intron (SNP) | VAF 75/280 reads (27%) | catalogued as COSV55040342; called by muse, mutect2, varscan2
